Somatic mutation profile of tumor specimen TCGA-G3-A5SM-01A (aliquot TCGA-G3-A5SM-01A-12D-A28X-10) from TCGA case TCGA-G3-A5SM, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 58.1 years (21,236 days).
Specimen TCGA-G3-A5SM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c399c8e-a64c-4570-bfb3-bbf93fca5382.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A5SM-10A (Blood Derived Normal), aliquot TCGA-G3-A5SM-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a509e94-eb62-4bf0-ac54-bd3fb71e8e46

The open-access MAF lists 136 somatic variants for this specimen: 94 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 39, Splice Site 5, Nonsense Mutation 3, 3'UTR 2, Splice Region 1, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2301A>C p.L767F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705638, COSV66706950; called by muse, mutect2, varscan2
- TP53 | c.994-2A>G p.X332_splice | Splice Site (SNP) | VAF 33/77 reads (43%) | hotspot (GDC flag); catalogued as rs867389695, CS159286, COSV52692098, COSV52692518, COSV53122371; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1100A>G p.H367R | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV50976954; called by muse, mutect2, varscan2
- ABCA1 | c.788A>G p.H263R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs763689519, COSV66067643; called by muse, mutect2, varscan2
- ANKRD52 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57285283; called by muse, mutect2, varscan2
- B4GALNT1 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57541759, COSV57543357; called by muse, mutect2, varscan2
- BTNL3 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100732244; called by muse, mutect2, varscan2
- CACNA1C | c.4280C>T p.P1427L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV59735382; called by muse, mutect2, varscan2
- CD300E | c.191C>G p.T64S | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100151250, COSV60790877; called by muse, mutect2, varscan2
- CERS1 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55929685; called by muse, mutect2, varscan2
- CHD7 | c.5842G>A p.V1948M | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.652); catalogued as COSV71112203; called by muse, mutect2, varscan2
- CHL1 | c.1324T>C p.F442L (on ENST00000397491 / NM_001253387.1; = p.F458L on NM_006614.4) | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV56596563; called by muse, mutect2, varscan2
- CHRND | c.51T>C p.C17= | Splice Region (SNP) | VAF 26/215 reads (12%) | catalogued as COSV51322288; called by muse, mutect2
- CKAP5 | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as COSV56369610; called by mutect2, varscan2
- CPQ | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as COSV55150504; called by muse, mutect2, varscan2
- CR2 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.466); catalogued as COSV65508303; called by muse, mutect2, varscan2
- CSNK1G3 | c.1285A>G p.T429A | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.014); catalogued as rs1366880605, COSV62055447; called by muse, mutect2, varscan2
- DAPL1 | c.58+2T>A p.X20_splice | Splice Site (SNP) | VAF 28/219 reads (13%) | catalogued as COSV59375361; called by muse, mutect2, varscan2
- DHX16 | c.1817A>T p.Q606L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV64564516; called by muse, mutect2, varscan2
- DOK6 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779449377, COSV66926062; called by muse, mutect2, varscan2
- DSCAML1 | c.2972G>A p.W991* (on ENST00000321322; = p.W931* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 12/178 reads (7%) | catalogued as COSV58394826; called by muse, mutect2
- DYRK2 | c.1187G>A p.G396E (on ENST00000344096 / NM_006482.3; = p.G323E on NM_003583.4) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59846663; called by muse, mutect2, varscan2
- EEF1A2 | c.1049C>G p.P350R | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV53206821; called by muse, mutect2, varscan2
- EXOC6B | c.1851G>T p.K617N | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV55560088, COSV99723971; called by muse, mutect2, varscan2
- FAM81B | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV51984112; called by muse, varscan2
- FBXO4 | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55852822; called by muse, mutect2, varscan2
- FHOD3 | c.580T>C p.W194R | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57177510; called by muse, mutect2, varscan2
- FRMPD2 | c.2383T>C p.Y795H | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV59719498; called by muse, mutect2, varscan2
- FRMPD3 | c.3989G>A p.R1330H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1171820532, COSV99346730; called by muse, mutect2, varscan2
- GABRG1 | c.866G>T p.W289L | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54956585; called by muse, mutect2, varscan2
- GALNT1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52453187, COSV99322348; called by muse, mutect2, varscan2
- HKDC1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.122); catalogued as COSV63577778; called by muse, mutect2, varscan2
- HMGCR | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV55316361; called by muse, mutect2, varscan2
- HTR2C | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.189); catalogued as rs77459121, COSV52215810; called by muse, mutect2, varscan2
- HTRA3 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV56470204, COSV56471641; called by muse, mutect2
- HYOU1 | c.679-2A>G p.X227_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as COSV68216237; called by muse, mutect2, varscan2
- IQSEC2 | c.2513G>A p.R838Q (on ENST00000642864 / NM_001111125.3; = p.R633Q on NM_015075.2) | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64726289; called by muse, mutect2
- IRS4 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV64534425; called by muse, mutect2, varscan2
- ITGA3 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50317942; called by muse, mutect2, varscan2
- ITPK1 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 50/149 reads (34%) | catalogued as COSV50896631; called by muse, mutect2, varscan2
- KDM5C | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as CD1211638, COSV62891170; called by muse, mutect2, varscan2
- KIF15 | c.1498C>A p.L500M | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58162104; called by muse, mutect2, varscan2
- KIF26A | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1274274925, COSV59467808; called by muse, mutect2, varscan2
- KIF26B | c.3524C>T p.T1175M | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs202113373; called by muse, mutect2
- KIF2B | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52132179, COSV99082059; called by muse, mutect2, varscan2
- KLK1 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56827368; called by muse, mutect2
- KRT39 | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs775535011, COSV62916903; called by muse, mutect2, varscan2
- KRTAP1-3 | c.472T>C p.C158R | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100727426, COSV60336397; called by muse, mutect2, varscan2
- LTB4R | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51866460; called by muse, mutect2, varscan2
- LY75 | c.4801G>A p.G1601R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55107945; called by muse, mutect2, varscan2
- MAGED1 | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.991); catalogued as COSV58515740; called by muse, mutect2, varscan2
- MANEA | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV62589950; called by muse, mutect2, varscan2
- MECOM | c.2600+1G>T p.X867_splice (on ENST00000468789 / NM_001105078.4; = p.X1055_splice on NM_004991.4) | Splice Site (SNP) | VAF 12/74 reads (16%) | catalogued as COSV52967316; called by muse, mutect2, varscan2
- MXRA5 | c.443A>C p.N148T | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.138); catalogued as COSV54239738; called by muse, mutect2, varscan2
- MYO3A | c.1816A>T p.N606Y | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56336221; called by muse, mutect2, varscan2
- N4BP2 | c.375T>G p.S125R | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54703613; called by muse, mutect2, varscan2
- NRCAM | c.3619C>T p.H1207Y (on ENST00000379028 / NM_001371124.1; = p.H1086Y on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV61040309; called by muse, mutect2, varscan2
- OR2T10 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774284253, COSV57897190; called by muse, mutect2, varscan2
- OR4A15 | c.98A>T p.Y33F | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as COSV59036026; called by muse, mutect2, varscan2
- OR5K4 | c.565T>A p.C189S | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61583922; called by muse, mutect2, varscan2
- OR8K1 | c.680T>G p.I227S | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV54403127; called by muse, mutect2, varscan2
- P4HA3 | c.506A>G p.D169G | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.7); catalogued as COSV59042440; called by mutect2, varscan2
- PARP10 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV57298657; called by muse, mutect2, varscan2
- PITPNM3 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV52596795, COSV52599872; called by muse, mutect2, varscan2
- PKHD1L1 | c.3398T>G p.V1133G | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV65746011; called by muse, mutect2
- PLXNB3 | c.1886C>A p.A629E | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV62798607; called by muse, varscan2
- PLXNB3 | c.4993G>A p.E1665K | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372327696, COSV62798626; called by muse, mutect2, varscan2
- PREX1 | c.2267G>A p.G756D | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1384353174, COSV64253438; called by muse, mutect2, varscan2
- RNASE2 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV58941300; called by muse, mutect2, varscan2
- RRP1B | c.1455A>T p.E485D | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.154); catalogued as COSV61479426; called by muse, mutect2, varscan2
- SALL3 | c.2141G>T p.R714L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73306173, COSV73306533; called by muse, mutect2, varscan2
- SCNN1A | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV57436265; called by muse, mutect2, varscan2
- SESN2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763209004, COSV53426564, COSV53428563; called by muse, mutect2, varscan2
- SLC22A14 | c.1622C>A p.P541H | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56198209; called by muse, mutect2, varscan2
- SMG6 | c.3240G>C p.K1080N | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as COSV53969862; called by muse, mutect2, varscan2
- SORCS1 | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.06); catalogued as rs762709776, COSV53877057; called by muse, mutect2, varscan2
- SPATA31D1 | c.3294C>A p.D1098E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.802); catalogued as COSV61197583; called by mutect2, varscan2
- SYNE1 | c.3505G>C p.E1169Q (on ENST00000367255 / NM_182961.4; = p.E1176Q on NM_033071.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV54989757, COSV55018278; called by muse, mutect2, varscan2
- TEX14 | c.372C>A p.N124K | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV53619945; called by muse, mutect2, varscan2
- TLE4 | c.762G>T p.L254F | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99512979; called by muse, mutect2, varscan2
- TLE4 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV99512981; called by muse, mutect2, varscan2
- TMEM176A | c.556-2A>G p.X186_splice | Splice Site (SNP) | VAF 20/102 reads (20%) | catalogued as COSV50242078; called by muse, mutect2, varscan2
- TPRN | c.1224C>A p.D408E | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV58808062; called by muse, mutect2, varscan2
- TRPC3 | c.1184C>T p.A395V (on ENST00000379645 / NM_001366479.2; = p.A322V on NM_003305.2) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.456); catalogued as COSV53377187; called by muse, mutect2, varscan2
- TSKU | c.1025C>A p.T342N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV60752122; called by muse, mutect2, varscan2
- TTI2 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV62452941; called by muse, mutect2, varscan2
- TTN | c.30013G>A p.D10005N (on ENST00000591111; = p.D9078N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/108 reads (34%) | PolyPhen benign (0.068); catalogued as rs1056294403, COSV60150831; called by muse, mutect2, varscan2
- UGT1A8 | c.511G>T p.G171* | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as COSV65080889; called by muse, mutect2
- XPOT | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV60346256; called by muse, mutect2, varscan2
- ZNF528 | c.959C>A p.T320N | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV64619913; called by muse, mutect2
- ZNF595 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs782325659; called by muse, mutect2, varscan2
- COG5 | c.1493_1495del p.A498del | In Frame Del (DEL) | VAF 15/94 reads (16%) | called by pindel, varscan2
- MICU3 | c.443del p.R148Hfs*8 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- VPS39 | c.2247dup p.S750Qfs*50 (on ENST00000348544 / NM_001301138.2; = p.S739Qfs*50 on NM_015289.5) | Frame Shift Ins (INS) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- ACTN3 | c.2631G>A p.K877= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV59749318; called by muse, mutect2, varscan2
- ADORA2A | c.1017C>T p.N339= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs759832709, COSV58379401; called by mutect2, varscan2
- AHNAK2 | c.843G>A p.S281= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as rs376708808, COSV60910255; called by muse, mutect2, varscan2
- ALDH2 | c.246C>T p.A82= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs574259526, COSV55668371; called by mutect2, varscan2
- BBX | c.1419C>T p.C473= | Silent (SNP) | VAF 93/238 reads (39%) | catalogued as COSV57887337; called by muse, mutect2, varscan2
- BRD8 | c.1092C>T p.I364= (on ENST00000254900 / NM_139199.2; = p.I437= on NM_006696.4) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs761550472, COSV50154603; called by muse, mutect2, varscan2
- CAPN5 | c.1902G>A p.Q634= (on ENST00000456580; = p.Q594= on NM_004055.5) | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as COSV53689141; called by muse, mutect2, varscan2
- CCP110 | c.1932A>G p.L644= | Silent (SNP) | VAF 127/319 reads (40%) | catalogued as COSV66817216; called by muse, mutect2, varscan2
- CLSTN2 | c.546G>A p.E182= | Silent (SNP) | VAF 81/221 reads (37%) | catalogued as rs977728342, COSV71721702; called by muse, mutect2, varscan2
- DNAI1 | c.1707C>T p.D569= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV54282113; called by muse, mutect2, varscan2
- DOCK4 | c.4461T>C p.I1487= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as COSV70239122; called by muse, varscan2
- FAM234A | c.1452C>A p.V484= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV51453038; called by muse, mutect2, varscan2
- FGD5 | c.2403G>T p.T801= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV53245769; called by muse, mutect2, varscan2
- FNDC1 | c.3897C>A p.R1299= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV51940902; called by muse, mutect2, varscan2
- HCN4 | c.1722C>T p.S574= | Silent (SNP) | VAF 77/100 reads (77%) | catalogued as rs750941501, COSV56084710; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- HTRA3 | c.993C>T p.A331= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV56471652; called by muse, mutect2
- ITGA7 | c.1080G>C p.L360= (on ENST00000555728; = p.L316= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as COSV57696769; called by muse, mutect2, varscan2
- KMT2C | c.10251G>A p.Q3417= | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as rs1003521577, COSV51281614; called by muse, mutect2, varscan2
- KRT2 | c.1143T>C p.T381= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV59011153; called by muse, mutect2, varscan2
- KRTAP19-1 | c.24C>T p.Y8= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as rs369209975; called by muse, mutect2, varscan2
- KRTAP8-1 | c.6C>G p.L2= | Silent (SNP) | VAF 46/158 reads (29%) | catalogued as COSV61598128; called by muse, mutect2, varscan2
- MKRN3 | c.399G>A p.S133= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs905116093, COSV58810449; called by muse, mutect2, varscan2
- MLST8 | c.495G>T p.L165= | Silent (SNP) | VAF 83/205 reads (40%) | catalogued as rs762777522, COSV57029374; called by muse, mutect2, varscan2
- NMRAL1 | c.75G>A p.L25= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV52060364; called by muse, mutect2, varscan2
- OR4C11 | c.75G>T p.V25= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV56353907; called by muse, mutect2, varscan2
- PCDHB8 | c.1218A>G p.T406= | Silent (SNP) | VAF 93/480 reads (19%) | catalogued as rs781920804, COSV50781678; called by muse, mutect2, varscan2
- PCLO | c.108G>T p.A36= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as COSV61644123; called by muse, mutect2, varscan2
- PPP1R42 | c.207T>C p.N69= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100221099, COSV61208360; called by muse, mutect2, varscan2
- PTX4 | c.1413C>T p.C471= (on ENST00000447419 / NM_001328608.2; = p.C466= on NM_001013658.1) | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV53517635; called by muse, mutect2, varscan2
- PUF60 | c.1068A>T p.P356= (on ENST00000526683 / NM_001362896.2; = p.P339= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 79/176 reads (45%) | catalogued as COSV57589060; called by muse, mutect2, varscan2
- RP1L1 | c.3060G>A p.Q1020= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV66756703; called by muse, mutect2, varscan2
- SLC6A18 | c.1569C>T p.V523= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV57252193; called by muse, mutect2, varscan2
- STAG2 | c.1548G>A p.R516= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV54362374; called by muse, mutect2, varscan2
- STOX1 | c.1359C>T p.P453= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV53815768; called by muse, mutect2, varscan2
- TMEM26 | c.153G>A p.A51= | Silent (SNP) | VAF 24/194 reads (12%) | catalogued as rs761541357, COSV67492899; called by muse, mutect2, varscan2
- TRIO | c.3300G>A p.T1100= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as rs1365720508, COSV60086337; called by muse, varscan2
- TTBK1 | c.195G>A p.E65= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV52492952; called by muse, mutect2, varscan2
- TTF2 | c.3363A>G p.T1121= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV65632948; called by muse, varscan2
- ZNF835 | c.1323G>A p.T441= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV73379529; called by muse, mutect2, varscan2
- GABRE | c.784+156A>T | Intron (SNP) | VAF 25/178 reads (14%) | catalogued as COSV64820121; called by muse, mutect2, varscan2
- GPRC5A | c.*3347G>A | 3'UTR (SNP) | VAF 9/175 reads (5%) | catalogued as COSV50008462; called by muse, mutect2
- SLC15A2 | c.*2G>A | 3'UTR (SNP) | VAF 40/105 reads (38%) | catalogued as COSV99815818; called by muse, mutect2, varscan2
